CPTAC case C3L-02800 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ce4270b6-9c22-42b0-87c9-bff964cb3da3

Demographics
Sex at birth: female; Year of birth: 1955; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 62.7 years (22,902 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage IIIC1; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,868 days (5.1 years); Progression or recurrence: no; Days to last follow up: 1,868 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 8 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 7; Margin status: Indeterminate.

Follow-up (6 entries)
- Days to follow up: 333 days; Disease response: Tumor Free.
- Days to follow up: 782 days (2.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,099 days (3.0 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 1,099 days (3.0 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,476 days (4.0 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,868 days (5.1 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 44.45 kg; Height: 160.02 cm; BMI: 17.36.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02800-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 561 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02800-21: Section location: Anterior and Posterior Endometrium; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-02800-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
